Gene-level copy-number profile of tumor specimen TCGA-CD-8527-01A from TCGA case TCGA-CD-8527, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 72.6 years (26,503 days).
Specimen TCGA-CD-8527-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.af4ba9a7-1e34-4354-8ed6-df15aefc25aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8527-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/81f178d4-69c5-443d-839b-d23206664fab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,602; copy number 2: 24,146; copy number 3: 24,005; copy number 4: 4,847; copy number 5: 2,075; copy number 6: 457; copy number 7: 325; copy number 8: 69; copy number 11: 19; copy number 17: 192; copy number 23: 19; copy number 27: 12; copy number 31: 22; copy number 34: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8527-01A-11D-2338-01): tumor purity 0.75, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 662 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:191,952,349–193,697,811, 22 genes, copy number 8: AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA.
- chr7:87,627,548–95,296,415, 111 genes, copy number 17–23 (within-gene range 2–23) (broad region; genes not listed).
- chr7:95,297,676–100,221,488, 134 genes, copy number 17–31 (within-gene range 3–31) (broad region; genes not listed).
- chr8:140,505,813–141,195,808, 13 genes, copy number 7: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr8:141,224,288–141,226,947, 1 gene, copy number 7: AC011676.5.
- chr10:116,538,183–133,761,125, 311 genes, copy number 7 (broad region; genes not listed).
- chr12:25,004,342–25,885,855, 23 genes, copy number 34 (within-gene range 2–34): IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1.
- chr17:31,830,731–32,491,253, 40 genes, copy number 8: AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,495,536–32,531,492, 7 genes, copy number 8: AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.

Autosomal genes at a single copy (total copy number 1): 2,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
